CCDI case PBCCEA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b431c97b-7fd2-4b68-9b9b-2b02dba7caae

Demographics
Sex at birth: male; Race: american indian or alaska native; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,456 days).

Biospecimens (3 samples)
- Sample 0DO7LX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DO7M8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DO7ME: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
